Gene-level copy-number profile of tumor specimen TCGA-AO-A03L-01A from TCGA case TCGA-AO-A03L, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 34.1 years (12,443 days).
Specimen TCGA-AO-A03L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.c5f3f2c3-0c41-4b3d-91d5-767a54746db9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A03L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/88282030-6893-43e5-9a9f-9447edbc3d05

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 101; copy number 2: 20,013; copy number 3: 14,597; copy number 4: 22,408; copy number 5: 93; copy number 6: 1,988; copy number 7: 184; copy number 8: 7; copy number 9: 79; copy number 10: 9; copy number 11: 132; copy number 12: 32; copy number 14: 77; copy number 15: 34; copy number 16: 11; copy number 17: 42; copy number 20: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A03L-01A-41D-A059-01): tumor purity 0.51, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 421 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:71,382,601–71,549,608, 9 genes, copy number 10: ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9.
- chr12:459,939–684,127, 7 genes, copy number 9 (within-gene range 6–9): B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455.
- chr12:781,133–781,258, 1 gene, copy number 9: RNU4ATAC16P.
- chr12:1,529,891–1,788,674, 7 genes, copy number 9: WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14.
- chr17:52,862,121–54,670,420, 13 genes, copy number 9 (within-gene range 2–9): LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1.
- chr17:61,942,605–69,553,865, 228 genes, copy number 11–20 (within-gene range 4–20) (broad region; genes not listed).
- chr19:57,230,802–58,216,561, 74 genes, copy number 12–17 (broad region; genes not listed).
- chr20:35,201,745–37,603,185, 82 genes, copy number 9–16 (within-gene range 4–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
